Somatic mutation profile of tumor specimen TCGA-2G-AAHA-01A (aliquot TCGA-2G-AAHA-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAHA, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 48.3 years (17,658 days).
Specimen TCGA-2G-AAHA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4821fa6-02b9-4a11-ab7b-115e570016b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAHA-10A (Blood Derived Normal), aliquot TCGA-2G-AAHA-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec1eb4a7-205c-4f82-a106-8f1880de2c5c

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2446G>C p.D816H | Missense Mutation (SNP) | VAF 22/94 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs121913506, COSV55386862, COSV55387240, COSV55408330; ClinVar: likely pathogenic / other / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 46/267 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANO7 | c.991C>T p.P331S (on ENST00000274979; = p.P277S on NM_001370694.2) | Missense Mutation (SNP) | VAF 72/463 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755827220; called by muse, mutect2, varscan2
- APH1A | c.781A>G p.I261V | Missense Mutation (SNP) | VAF 116/381 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1553849764; called by muse, mutect2, varscan2
- APOA4 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs558629714; called by muse, mutect2, varscan2
- MYO1D | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2
- MYOCD | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PNN | c.2092G>T p.G698C | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAPGEF1 | c.1784_1786del p.S595del | In Frame Del (DEL) | VAF 19/135 reads (14%) | called by mutect2, pindel, varscan2
- RESF1 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- SCAMP2 | c.461A>C p.Y154S | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- BCL2L14 | c.129C>T p.F43= | Silent (SNP) | VAF 28/149 reads (19%) | called by muse, mutect2, varscan2
- PRX | c.2322G>T p.V774= | Silent (SNP) | VAF 32/86 reads (37%) | called by muse, mutect2, varscan2
- VPS35L | chr16:19555556 C>A | 5'Flank (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2
